Somatic mutation profile of tumor specimen 0DVM1G from CCDI case PBCMYV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.3 years (3,745 days).
Specimen 0DVM1G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aec9f875-276f-4852-9844-2088fb936a77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVM1S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/437fb72f-07ab-4638-92b1-e95aed3473aa

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 1, 3'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNB4 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs774714066, COSV99929505; called by muse, mutect2, varscan2
- PLK2 | c.2014C>T p.R672* | Nonsense Mutation (SNP) | VAF 99/343 reads (29%) | catalogued as COSV57106538; called by muse, mutect2, varscan2
- LDB3 | c.*24C>T | 3'UTR (SNP) | VAF 57/174 reads (33%) | catalogued as rs200688014; called by muse, mutect2, varscan2
